HCMI case HCM-BROD-0038-C41 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea983695-b464-44d5-afe7-c5ab4366aad7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2000; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.0; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Bone, NOS; Classification of tumor: primary; Age at diagnosis: 16.2 years (5,911 days); Prior malignancy: no; Prior treatment: Yes; Enneking msts grade: High Grade (G2); Enneking msts metastasis: No Metastasis (M0); Enneking msts tumor site: Extracompartmental (T2).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Doxorubicin + Methotrexate; Treatment intent type: Neoadjuvant; Regimen or line of therapy: MAP; Days to treatment start: 0 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 549 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Ifosfamide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 610 days (1.7 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 669 days (1.8 years); Disease response: Stable Disease; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0038-C41-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0038-C41-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
- Sample HCM-BROD-0038-C41-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen.
